Somatic mutation profile of tumor specimen TCGA-DA-A1I8-06A (aliquot TCGA-DA-A1I8-06A-11D-A197-08) from TCGA case TCGA-DA-A1I8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 66.1 years (24,161 days).
Specimen TCGA-DA-A1I8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0133b28-8184-41ca-abda-83a8afb1b84b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1I8-10A (Blood Derived Normal), aliquot TCGA-DA-A1I8-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4976371-c49d-4539-baea-e4cc0433848f

The open-access MAF lists 214 somatic variants for this specimen: 128 protein-altering or splice-affecting, 84 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 84, Nonsense Mutation 5, Splice Region 3, Splice Site 2, Intron 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/95 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACAP1 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs1447385577; called by muse, mutect2
- ACSL5 | c.386C>T p.S129L (on ENST00000354273; = p.S185L on NM_016234.3) | Missense Mutation (SNP) | VAF 87/133 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1283997883, COSV61132240; called by muse, mutect2, varscan2
- ADAM18 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV55854126; called by muse, mutect2, varscan2
- ADGRB3 | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV53238654; called by muse, mutect2, varscan2
- ADGRG4 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as COSV54965460; called by muse, mutect2, varscan2
- AFP | c.893A>T p.K298I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs369341269; called by muse, mutect2, varscan2
- ANK1 | c.996C>G p.D332E | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV55886755, COSV55893775; called by muse, mutect2, varscan2
- ANO4 | c.1565G>A p.G522E (on ENST00000392977 / NM_001286615.2; = p.G487E on NM_178826.4) | Missense Mutation (SNP) | VAF 99/293 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54606197; called by muse, mutect2, varscan2
- APBA2 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV68794734; called by muse, mutect2, varscan2
- BPNT2 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV52908895; called by muse, mutect2, varscan2
- CCDC66 | c.1282A>C p.I428L (on ENST00000394672 / NM_001353147.1; = p.I394L on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV58308756; called by muse, mutect2, varscan2
- CD80 | c.681G>C p.Q227H | Missense Mutation (SNP) | VAF 74/121 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs1301170000, COSV51803285; called by muse, varscan2
- CD80 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 80/126 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51803307; called by muse, varscan2
- CECR2 | c.3833C>T p.S1278F (on ENST00000342247 / NM_001290047.2; = p.S1094F on NM_001290046.1) | Missense Mutation (SNP) | VAF 137/235 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs1192165901, COSV52839550, COSV52847285; called by muse, mutect2, varscan2
- CEP250 | c.5765G>A p.R1922K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV61173864; called by muse, mutect2, varscan2
- CHD1 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52344246; called by muse, mutect2, varscan2
- CHGB | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs759534931, COSV66761604; called by muse, mutect2, varscan2
- CHGB | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as COSV66761608; called by muse, mutect2, varscan2
- CLIP4 | c.1625A>G p.Y542C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs769810816, COSV60752237; called by muse, mutect2, varscan2
- CNGB3 | c.371T>A p.I124K | Missense Mutation (SNP) | VAF 107/334 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV60697329; called by muse, mutect2, varscan2
- COL22A1 | c.846G>A p.E282= | Splice Region (SNP) | VAF 13/38 reads (34%) | catalogued as COSV57357089; called by muse, mutect2, varscan2
- COL26A1 | c.532G>A p.E178K (on ENST00000313669 / NM_001278563.3; = p.E176K on NM_133457.4) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV58131254; called by muse, mutect2
- COL4A5 | c.3957G>A p.M1319I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.117); catalogued as COSV60357688; called by muse, mutect2, varscan2
- COMMD4 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV51191093; called by muse, mutect2, varscan2
- CUX2 | c.4109G>A p.G1370E | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.036); catalogued as COSV55645955; called by muse, mutect2, varscan2
- DENND5A | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV60237490; called by muse, mutect2, varscan2
- DHCR7 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs752603560, COSV62796527; called by muse, mutect2, varscan2
- DMD | c.8488C>T p.R2830W | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1569547242, COSV58947733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.12910C>T p.R4304C | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1312861905, COSV59476203; called by muse, mutect2, varscan2
- DNAH9 | c.6185C>T p.P2062L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV52373837, COSV99307425; called by muse, mutect2, varscan2
- DSCAM | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68652820; called by muse, mutect2, varscan2
- EFTUD2 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV68182650; called by muse, mutect2, varscan2
- EIF2D | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs782097617; called by muse, mutect2, varscan2
- ENOX2 | c.352C>T p.P118S (on ENST00000338144 / NM_001382520.1; = p.P89S on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV57657342; called by muse, mutect2, varscan2
- EPB41 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV58053202; called by muse, mutect2, varscan2
- ERV3-1 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1414930366, COSV51429691; called by muse, mutect2
- F8 | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1317695607, CM080272, CM1510594, COSV64273820; called by muse, mutect2, varscan2
- FANCE | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as rs759782690, COSV57690966, COSV57691237; called by muse, mutect2, varscan2
- FSTL5 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs1205161078, COSV60182816, COSV60201147; called by muse, mutect2, varscan2
- GABRG1 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV54952975; called by muse, mutect2, varscan2
- GDF2 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs200288011; called by muse, mutect2, varscan2
- GFI1B | c.734C>G p.T245R | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59745654, COSV59746806; called by muse, mutect2, varscan2
- GPR85 | c.623T>A p.F208Y | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51785099; called by muse, mutect2, varscan2
- GRHL2 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.16); catalogued as COSV52553693; called by muse, mutect2, varscan2
- GRID1 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373525033, COSV60024599; called by muse, mutect2, varscan2
- GUCY2F | c.1791+1G>A p.X597_splice | Splice Site (SNP) | VAF 89/165 reads (54%) | catalogued as COSV54307739, COSV99485519; called by muse, mutect2, varscan2
- GZMA | c.681del p.F228Lfs*27 | Frame Shift Del (DEL) | VAF 38/106 reads (36%) | catalogued as rs1432205073, COSV57050842; called by mutect2, pindel, varscan2
- HEXD | c.37C>T p.H13Y | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57343058; called by muse, mutect2, varscan2
- IGLV9-49 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs753445726; called by muse, mutect2
- IRF2 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.164); catalogued as COSV66930402; called by muse, mutect2, varscan2
- KCNQ2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1568916986, COSV60438752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1210 | c.2900C>T p.P967L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as COSV68179786; called by muse, mutect2, varscan2
- KIR2DL1 | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 92/152 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV52414941; called by muse, mutect2, varscan2
- KLHDC7A | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1553122963, COSV68769075; called by muse, mutect2, varscan2
- KRTAP5-10 | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV64795845; called by muse, mutect2, varscan2
- LAIR1 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57309508; called by muse, mutect2, varscan2
- LINGO2 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs758213532, COSV58063818; called by muse, varscan2
- LZTFL1 | c.522+1G>C p.X174_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as COSV56112396; called by muse, mutect2, varscan2
- MDGA1 | c.2667G>A p.Q889= | Splice Region (SNP) | VAF 15/70 reads (21%) | catalogued as COSV51801052; called by muse, mutect2, varscan2
- MGA | c.4352C>T p.P1451L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54961879; called by muse, mutect2, varscan2
- MGAM | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV71885992; called by muse, mutect2, varscan2
- MGAT5B | c.2074T>C p.W692R (on ENST00000569840 / NM_001199172.2; = p.W690R on NM_144677.3) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.998); catalogued as COSV56935948; called by muse, mutect2
- MTHFD1 | c.997A>G p.K333E | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV53703316; called by muse, mutect2, varscan2
- MTUS1 | c.2058G>T p.M686I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as COSV50582922; called by muse, mutect2, varscan2
- MUC17 | c.10156G>A p.G3386S | Missense Mutation (SNP) | VAF 51/566 reads (9%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.986); catalogued as rs770522694; called by muse, mutect2
- MUC17 | c.12199C>T p.P4067S | Missense Mutation (SNP) | VAF 118/166 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60301293; called by muse, mutect2, varscan2
- MUC5B | c.13156C>T p.P4386S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs776488809, COSV71594961; called by muse, mutect2, varscan2
- MYOM2 | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50764018; called by muse, mutect2, varscan2
- MYPOP | c.1109C>A p.P370Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as rs764832787; called by mutect2, varscan2
- NCOA6 | c.5263C>T p.P1755S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs755991725, COSV62867413; called by muse, mutect2, varscan2
- NEB | c.7774G>A p.D2592N | Missense Mutation (SNP) | VAF 142/524 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV51455503; called by muse, mutect2, varscan2
- NEB | c.5131C>T p.L1711F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV50827992, COSV50829947; called by muse, mutect2, varscan2
- NGEF | c.749A>G p.N250S | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.051); catalogued as COSV50950992; called by muse, mutect2, varscan2
- NPAT | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.188); catalogued as COSV53721405; called by muse, mutect2, varscan2
- NPC1 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as CM990940, COSV52583156; called by muse, mutect2, varscan2
- NUP160 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV65855786; called by muse, mutect2, varscan2
- NUP188 | c.4339G>C p.E1447Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.34); catalogued as COSV65331846; called by muse, mutect2, varscan2
- NXF3 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67704981; called by muse, mutect2, varscan2
- OR4C46 | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1448888593, COSV100060602, COSV60221042; called by muse, mutect2, varscan2
- OR52B6 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61447187; called by muse, mutect2
- OR6K3 | c.508C>T p.L170F (on ENST00000368146; = p.L154F on NM_001005327.2) | Missense Mutation (SNP) | VAF 59/75 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs1307958236, COSV63746386; called by muse, mutect2, varscan2
- OR6M1 | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs760500007, COSV58433639; called by muse, varscan2
- PADI6 | c.1996T>G p.C666G | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as COSV61885652; called by muse, mutect2, varscan2
- PASK | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs958374516, COSV52159526; called by muse, mutect2, varscan2
- PATJ | c.3077C>T p.S1026F | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV57170779; called by muse, mutect2, varscan2
- PIGV | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0.081); catalogued as COSV50302502; called by muse, mutect2, varscan2
- PKD1L1 | c.5448G>A p.V1816= | Splice Region (SNP) | VAF 19/79 reads (24%) | catalogued as COSV56976466; called by muse, mutect2, varscan2
- PKHD1L1 | c.5125G>A p.A1709T | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV65751466; called by muse, mutect2, varscan2
- POLI | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54191524; called by muse, mutect2
- PRR11 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV51878969; called by muse, mutect2, varscan2
- PSRC1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 56/328 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100883543; called by muse, mutect2, varscan2
- PTK7 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV57851261; called by muse, mutect2, varscan2
- PTPRB | c.4090C>T p.R1364W | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756418407, COSV54251557; called by muse, varscan2
- QPRT | c.572C>G p.A191G | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as COSV54880474; called by muse, mutect2, varscan2
- RP1 | c.3844C>T p.P1282S | Missense Mutation (SNP) | VAF 86/155 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs866399055, COSV55111239; called by muse, mutect2, varscan2
- RSF1 | c.2530C>T p.R844* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as COSV57836823; called by muse, mutect2, varscan2
- RTP2 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV64079399; called by muse, mutect2, varscan2
- RYR1 | c.4645C>T p.P1549S | Missense Mutation (SNP) | VAF 57/76 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62093801; called by muse, mutect2, varscan2
- SAMD9 | c.3715C>T p.P1239S | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV66077340; called by muse, mutect2, varscan2
- SECTM1 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.056); catalogued as rs199689650, COSV53940313, COSV99486139; called by muse, mutect2, varscan2
- SETD5 | c.3793C>A p.H1265N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV56716789; called by muse, mutect2, varscan2
- SFXN1 | c.370A>G p.N124D | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58494996; called by muse, mutect2, varscan2
- SLC36A2 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs1335075738, COSV58861935; called by muse, mutect2
- SLC38A1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV67064801; called by muse, mutect2, varscan2
- SLC5A3 | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 294/608 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62973005; called by muse, mutect2, varscan2
- SLC9A2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 162/332 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.035); catalogued as rs61743555, COSV52128997; called by muse, varscan2
- SNAP91 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV52132803; called by muse, mutect2, varscan2
- TBX18 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63738082; called by muse, mutect2, varscan2
- TCF23 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as COSV56079015; called by muse, mutect2, varscan2
- TENM3 | c.5117T>C p.I1706T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV69317622; called by muse, mutect2, varscan2
- TENM3 | c.6106G>A p.E2036K | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV69301424; called by muse, mutect2, varscan2
- TNFRSF8 | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV55800236; called by muse, mutect2, varscan2
- TTC9 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs776992939, COSV56447784; called by muse, mutect2, varscan2
- TTN | c.102637C>T p.Q34213* (on ENST00000591111; = p.Q26789* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as COSV60303397; called by muse, mutect2, varscan2
- TTN | c.97627G>A p.E32543K (on ENST00000591111; = p.E25119K on NM_003319.4) | Missense Mutation (SNP) | VAF 48/125 reads (38%) | PolyPhen probably damaging (0.994); catalogued as rs776306284, COSV59965488; called by muse, mutect2, varscan2
- TTN | c.94573G>A p.E31525K (on ENST00000591111; = p.E24101K on NM_003319.4) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | PolyPhen possibly damaging (0.541); catalogued as COSV60202592; called by muse, mutect2, varscan2
- UBE2I | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as COSV57646631; called by muse, mutect2, varscan2
- VPS26A | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54967368, COSV54969370; called by muse, mutect2, varscan2
- VPS4A | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as COSV54751980; called by muse, mutect2, varscan2
- ZNF217 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV56601738; called by muse, mutect2, varscan2
- ZNF334 | c.1244T>C p.F415S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV61619955; called by muse, mutect2, varscan2
- ATRN | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- C17orf98 | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EIF2D | c.1371G>A p.W457* | Nonsense Mutation (SNP) | VAF 20/30 reads (67%) | called by muse, mutect2
- KRT31 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- MUC17 | c.10157G>A p.G3386D | Missense Mutation (SNP) | VAF 51/566 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR56B1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC004922.1 | c.1239G>A p.L413= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as rs768810752, COSV53164738; called by muse, mutect2, varscan2
- ACAP1 | c.279C>T p.S93= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV50136528; called by muse, mutect2
- APOBEC3C | c.171C>T p.N57= | Silent (SNP) | VAF 60/90 reads (67%) | catalogued as rs745498036, COSV63865376, COSV63865614; called by muse, mutect2, varscan2
- ATRN | c.1144C>T p.L382= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs1485060195; called by muse, mutect2, varscan2
- BICD2 | c.2211G>A p.K737= | Silent (SNP) | VAF 42/55 reads (76%) | catalogued as COSV63550747; called by muse, varscan2
- C17orf78 | c.477G>A p.G159= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2
- CALCOCO1 | c.300C>T p.F100= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs772966574, COSV50421851; called by muse, mutect2, varscan2
- CCKAR | c.78G>A p.T26= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs1274976038, COSV55163129; called by muse, mutect2, varscan2
- CDH16 | c.504G>A p.L168= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV55339329; called by muse, mutect2, varscan2
- CFH | c.1785C>T p.F595= | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as rs763709710, COSV100808530, COSV66412647; called by muse, mutect2, varscan2
- CLDN23 | c.508C>T p.L170= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs781568102, COSV67731668; called by muse, mutect2, varscan2
- CPEB3 | c.1593C>T p.N531= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as COSV56462251; called by muse, mutect2, varscan2
- CTAGE1 | c.291G>A p.L97= | Silent (SNP) | VAF 82/207 reads (40%) | catalogued as rs1568128465, COSV66944546; called by muse, mutect2, varscan2
- DOK1 | c.354C>T p.A118= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV51212924; called by muse, mutect2, varscan2
- EPHA6 | c.2619C>T p.L873= (on ENST00000389672 / NM_001080448.3; = p.L265= on NM_173655.4) | Silent (SNP) | VAF 29/219 reads (13%) | catalogued as COSV67591615; called by muse, mutect2, varscan2
- EPHB6 | c.2700G>A p.Q900= | Silent (SNP) | VAF 53/340 reads (16%) | catalogued as COSV63893392; called by muse, mutect2, varscan2
- ERICH3 | c.1230G>A p.P410= | Silent (SNP) | VAF 56/104 reads (54%) | catalogued as rs375773806; called by muse, mutect2, varscan2
- ETS2 | c.981A>G p.P327= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV62874157; called by muse, mutect2, varscan2
- F8 | c.1401C>T p.I467= | Silent (SNP) | VAF 58/80 reads (73%) | catalogued as COSV64277291, COSV64278036; called by muse, varscan2
- FADS6 | c.333G>A p.K111= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1341180186, COSV59603635; called by muse, mutect2
- GIMAP8 | c.1743C>T p.N581= | Silent (SNP) | VAF 23/175 reads (13%) | catalogued as COSV56233501; called by muse, mutect2, varscan2
- GUCY2C | c.1854C>T p.T618= | Silent (SNP) | VAF 53/113 reads (47%) | catalogued as COSV53794913; called by muse, varscan2
- HPCAL1 | c.105C>T p.L35= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV57148919; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.22C>T p.L8= | Silent (SNP) | VAF 49/483 reads (10%) | catalogued as rs748438833; called by muse, mutect2, varscan2
- IQCJ | c.468C>T p.L156= | Silent (SNP) | VAF 41/69 reads (59%) | called by muse, mutect2, varscan2
- KL | c.2865C>T p.G955= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV66309102; called by muse, mutect2, varscan2
- KRT18 | c.555C>T p.L185= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV66316624; called by muse, mutect2, varscan2
- KRT31 | c.957C>T p.T319= | Silent (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- KRT35 | c.669C>T p.S223= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs1454803960, COSV55844440; called by muse, mutect2, varscan2
- KRT78 | c.975G>A p.T325= | Silent (SNP) | VAF 56/168 reads (33%) | catalogued as rs140207612; called by muse, mutect2, varscan2
- LETMD1 | c.462C>T p.V154= | Silent (SNP) | VAF 46/183 reads (25%) | catalogued as COSV50399749; called by muse, mutect2, varscan2
- LMCD1 | c.729C>T p.C243= | Silent (SNP) | VAF 34/224 reads (15%) | catalogued as rs758954010, COSV50091659; called by muse, mutect2, varscan2
- LRRC4C | c.1584C>T p.I528= | Silent (SNP) | VAF 53/95 reads (56%) | catalogued as COSV53436533; called by muse, mutect2, varscan2
- MAP4K3 | c.1668C>T p.P556= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV55717576; called by muse, mutect2, varscan2
- MED1 | c.4533T>C p.D1511= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs1264753346, COSV56128126; called by muse, mutect2, varscan2
- MRC2 | c.2316C>T p.F772= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as COSV57638421; called by muse, mutect2, varscan2
- MTUS2 | c.1018C>T p.L340= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV101462010, COSV70921748; called by muse, mutect2, varscan2
- MXRA5 | c.3693G>A p.R1231= | Silent (SNP) | VAF 49/84 reads (58%) | catalogued as rs761573472, COSV54248310; called by muse, mutect2, varscan2
- MYH8 | c.3366G>A p.G1122= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs932307194, COSV67971421; called by muse, varscan2
- NAAA | c.333G>A p.A111= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV54433692; called by muse, mutect2, varscan2
- NCOR2 | c.1917G>A p.R639= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV62303487; called by muse, mutect2, varscan2
- OPCML | c.69C>T p.F23= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV59446716; called by muse, mutect2, varscan2
- OR11H4 | c.375G>A p.L125= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs1001395304, COSV59560831; called by muse, mutect2, varscan2
- OR51A4 | c.202T>C p.L68= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as rs1422710218, COSV66749998; called by muse, mutect2, varscan2
- OR9A2 | c.33C>T p.F11= | Silent (SNP) | VAF 50/85 reads (59%) | catalogued as rs754460396, COSV63306440; called by muse, mutect2, varscan2
- PCDHA7 | c.150G>A p.Q50= | Silent (SNP) | VAF 79/103 reads (77%) | catalogued as COSV65347009; called by muse, mutect2, varscan2
- PCYOX1L | c.379C>T p.L127= | Silent (SNP) | VAF 39/54 reads (72%) | catalogued as rs765148776, COSV51005024; called by muse, mutect2, varscan2
- PDZD2 | c.708C>T p.G236= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV56870891; called by muse, mutect2, varscan2
- PLB1 | c.1608G>A p.K536= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as COSV59834406; called by muse, mutect2, varscan2
- PLCL2 | c.1872C>T p.I624= (on ENST00000615277 / NM_001144382.2; = p.I498= on NM_015184.5) | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV67624801; called by muse, mutect2, varscan2
- PLXNA1 | c.2994C>T p.G998= | Silent (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- PLXNA4 | c.3486C>T p.I1162= | Silent (SNP) | VAF 182/250 reads (73%) | catalogued as COSV58156218; called by muse, mutect2, varscan2
- POTEF | c.2428C>T p.L810= | Silent (SNP) | VAF 63/231 reads (27%) | catalogued as COSV62543597; called by muse, mutect2, varscan2
- PPFIA1 | c.2604C>T p.A868= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV54140130; called by muse, mutect2, varscan2
- PRSS57 | c.243C>T p.L81= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as COSV61386721; called by muse, mutect2, varscan2
- PSRC1 | c.240G>A p.E80= | Silent (SNP) | VAF 54/327 reads (17%) | catalogued as rs930758466; called by muse, mutect2, varscan2
- PTBP3 | c.1339C>T p.L447= | Silent (SNP) | VAF 54/76 reads (71%) | catalogued as rs1485455995, COSV57581940, COSV57586907; called by muse, mutect2, varscan2
- PTPRB | c.4089C>T p.C1363= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV54245494; called by muse, varscan2
- RBP3 | c.2202C>T p.F734= | Silent (SNP) | VAF 30/44 reads (68%) | called by muse, mutect2, varscan2
- RHBDF2 | c.831C>T p.F277= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV57422517; called by muse, mutect2, varscan2
- RLF | c.1644G>A p.Q548= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV65653042; called by muse, mutect2, varscan2
- RNF152 | c.207C>T p.L69= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV57188016; called by muse, mutect2
- SAMD4A | c.324C>T p.I108= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs773078791, COSV51887269; called by muse, mutect2, varscan2
- SCN8A | c.2787C>G p.V929= | Silent (SNP) | VAF 108/307 reads (35%) | catalogued as COSV61991892, COSV61992354; called by muse, mutect2, varscan2
- SDK2 | c.2157G>A p.Q719= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as rs1482324154, COSV66180557, COSV66195393; called by muse, mutect2, varscan2
- SEMA3D | c.1515C>T p.I505= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV52402987; called by muse, mutect2, varscan2
- SLC26A3 | c.957G>A p.G319= | Silent (SNP) | VAF 108/167 reads (65%) | catalogued as COSV60642334; called by muse, mutect2, varscan2
- SLC6A18 | c.831T>C p.S277= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV57254035; called by muse, mutect2, varscan2
- SLC7A10 | c.447C>T p.P149= | Silent (SNP) | VAF 45/57 reads (79%) | catalogued as rs762067791, COSV53506949; called by muse, mutect2, varscan2
- SPEG | c.6900C>T p.P2300= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs1177642344, COSV56678643; called by muse, mutect2, varscan2
- SSH1 | c.2961C>T p.F987= | Silent (SNP) | VAF 130/266 reads (49%) | catalogued as rs1346790352, COSV58459883; called by muse, mutect2, varscan2
- TAS2R41 | c.742C>T p.L248= | Silent (SNP) | VAF 19/145 reads (13%) | catalogued as COSV68765821; called by muse, mutect2, varscan2
- TRIM49 | c.33G>A p.G11= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs746480306, COSV61671837; called by mutect2, varscan2
- TRPM7 | c.561C>T p.A187= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV57921055; called by muse, mutect2, varscan2
- UBE2I | c.261C>T p.Y87= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs1379687423, COSV57647626; called by muse, mutect2, varscan2
- UBN2 | c.3051T>C p.A1017= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as rs1460282695, COSV56034902; called by muse, mutect2, varscan2
- VPS13B | c.456C>T p.N152= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV62024870; called by muse, mutect2, varscan2
- WDFY3 | c.8817A>G p.Q2939= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV55712448; called by muse, mutect2, varscan2
- WDR17 | c.1644T>A p.V548= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV54582377; called by muse, mutect2, varscan2
- WDR49 | c.1041C>T p.P347= (on ENST00000308378 / NM_001366158.1; = p.P688= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs749501243, COSV57716615; called by muse, mutect2, varscan2
- XRN2 | c.1998C>T p.Y666= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV65871344; called by muse, mutect2, varscan2
- ZMAT1 | c.912C>T p.F304= | Silent (SNP) | VAF 58/101 reads (57%) | catalogued as rs777269094, COSV65659953; called by muse, mutect2, varscan2
- ZNF682 | c.78G>A p.Q26= | Silent (SNP) | VAF 35/43 reads (81%) | catalogued as COSV62068347; called by muse, mutect2
- ZNFX1 | c.2025C>T p.T675= | Silent (SNP) | VAF 95/174 reads (55%) | catalogued as COSV65578745; called by muse, mutect2, varscan2
- PTMA | c.*531T>G | 3'UTR (SNP) | VAF 43/111 reads (39%) | catalogued as COSV100398449; called by muse, mutect2, varscan2
- TTN | c.10361-3804T>C | Intron (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
